Somatic mutation profile of tumor specimen TARGET-20-PARZHT-09A (aliquot TARGET-20-PARZHT-09A-01D) from TARGET case TARGET-20-PARZHT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,498 days).
Specimen TARGET-20-PARZHT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c88a0c16-b644-47c2-998d-0fb316a42fe3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARZHT-14A (Bone Marrow Normal), aliquot TARGET-20-PARZHT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae3fbcf7-0867-4f6e-b0a3-c7590cd5d817

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2504A>T p.D835V | Missense Mutation (SNP) | VAF 16/174 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909646, COSV54042199, COSV54043241, COSV54057031; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ASXL1 | c.1900_1922del p.E635Rfs*15 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs766433101; called by mutect2, varscan2
- MYH2 | c.4000G>A p.A1334T | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as rs779257410, COSV55449691; called by muse, mutect2, varscan2
- SPI1 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV57026349; called by muse, mutect2, varscan2
